CCDI case PBCMIW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4bf83227-2166-4401-b4e6-5d51d715c249

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Dysembryoplastic neuroepithelial tumor: ICD-O-3 morphology code: 9413/0; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 15.3 years (5,577 days).

Biospecimens (3 samples)
- Sample 0DVPN1: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVPOO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample 0DVPP3: Tissue type: Normal; Specimen type: Peripheral Whole Blood. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
